Surgical pathology report (de-identified scan), TCGA case TCGA-DU-7008, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-7008-01A (Primary Tumor).

PATHOLOGICAL DIAGNOSIS:

BRAIN BIOPSY, TEMPORAL LOBE: OLIGODENDROGLIOMA, GRADE B (MIB-1 ABOUT 8%).

Operation/Specimen: Brain. Temporal lobe.

Clinical History and Pre-Op Dx: [REDACTED] woman with a 7-8 cm lesion involving the temporal lobe and extending to the frontal lobe, diffuse.

GROSS PATHOLOGY:

A.

SPECIMEN: Brain.
FIXATIVE: Received fresh, 6 fragments, 1.0 cm across in aggregate. Tannish white, glistening, semi-firm. In toto #1 and 2.

INTRAOPERATIVE CONSULTATION, Brain: Infiltrating Glioma. [REDACTED]

[REDACTED])

B.

SPECIMEN: Received fresh, 3 fragments, 3.0 x 2.5 x 0.7 cm in aggregate. Semi-firm, glistening, tannish-white. In toto #3-5.

C.

SPECIMEN: 3, temporal lobe.
FIXATIVE: None.
GENERAL: A 2.3 x 1.7 x 0.8 cm. red to gray-tan fragment of brain tissue. Sectioned.
SECTIONS: X1, X2 - all.

[REDACTED]

MICROSCOPIC: Sections show an infiltrating oligodendroglioma with microcystic change in some areas. Microgemistocytic cells are frequently encountered. In more hypercellular areas, nuclear atypia and mitotic figures are noted. Vascular endothelial hyperplasia and necrosis are not seen. Labeling index of MIB-1 is about 8%. The tumor is classified as a grade B oligodendroglioma.

[REDACTED]

Source: NCI Genomic Data Commons file 0b909cf8-f115-4498-88ce-fee19d58e66c (TCGA-DU-7008.70AFF058-6C24-488C-89AE-3BD311595820.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).